Gene-level copy-number profile of tumor specimen ALCH-ABIM-TTP1-A from ALCHEMIST case ALCH-ABIM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.8 years (23,298 days).
Specimen ALCH-ABIM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 07a67f4c-44eb-47ec-9299-afe0ab036b04.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ABIM-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/39e70ef7-92a3-4377-b854-aaf5b111ef3e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 1,735; copy number 2: 54,011; copy number 3: 2,631; copy number 4: 12; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:241,869,600–241,873,823, 1 gene: RTP5.
- chr2:241,893,988–241,902,551, 1 gene (within-gene range 0–2): FAM240C.
- chr8:22,565,997–22,598,025, 2 genes (within-gene range 0–2): AC037459.3, PDLIM2.
- chr21:13,968,489–13,968,595, 1 gene (within-gene range 0–2): RNU6-954P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:2,234,251–2,234,499, 1 gene, copy number 5 (within-gene range 2–5): COX6B1P5.
- chr21:12,999,676–13,016,692, 1 gene, copy number 5: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 1,735. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
